Somatic mutation profile of tumor specimen 0DHFN2 from CCDI case PBBUDJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sertoli-Leydig cell tumor, poorly differentiated; Tissue or organ of origin: Ovary; Age at diagnosis: 12.3 years (4,475 days).
Specimen 0DHFN2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af8dc3ca-46ae-4042-8daa-011250529e32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHFL3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b0a2281-6313-4978-865b-05491e17617b

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 2, RNA 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>T p.E1813V | Missense Mutation (SNP) | VAF 285/619 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- MCEMP1 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 161/360 reads (45%) | catalogued as COSV58040414; called by muse, mutect2, varscan2
- PBXIP1 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 304/648 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368801895; called by muse, mutect2, varscan2
- SLC30A10 | c.897C>G p.I299M | Missense Mutation (SNP) | VAF 22/866 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV100751501; called by muse, mutect2
- DENND2C | c.2391A>T p.E797D (on ENST00000393274 / NM_001256404.2; = p.E740D on NM_198459.4) | Missense Mutation (SNP) | VAF 23/796 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2
- FAM47A | c.69_70del p.N23Kfs*51 | Frame Shift Del (DEL) | VAF 414/986 reads (42%) | called by mutect2, varscan2
- HMG20B | c.697C>A p.R233S | Missense Mutation (SNP) | VAF 229/483 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- ITGB1 | c.2302A>T p.K768* | Nonsense Mutation (SNP) | VAF 255/558 reads (46%) | called by muse, mutect2, varscan2
- C11orf40 | n.527G>C | RNA (SNP) | VAF 277/656 reads (42%) | catalogued as COSV56891862; called by muse, mutect2, varscan2
- PLEKHA4 | c.1667-15G>A | Intron (SNP) | VAF 162/343 reads (47%) | catalogued as rs1244725892; called by muse, mutect2, varscan2
